Gene-level copy-number profile of specimen HCM-BROD-0416-C71-85B from HCMI case HCM-BROD-0416-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 73.1 years (26,690 days).
Specimen HCM-BROD-0416-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 14.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0e6739f9-1507-4a21-b921-d20e7e84093e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0416-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/f14f6c8c-2411-407f-9454-e7f05cca2bc3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 1,896; copy number 2: 49,306; copy number 3: 6,968; copy number 4: 133; copy number 5: 30; copy number 29: 8; copy number 30: 3; copy number 33: 2; copy number 35: 3; copy number 37: 4.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:22,446,824–26,786,874, 23 genes: DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2.
- chr9:26,947,039–28,670,286, 22 genes (within-gene range 0–1): IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 50 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:5,419,827–5,606,655, 12 genes, copy number 5 (within-gene range 3–5): AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589, ACTB, AC006483.2, AC006483.1, FSCN1.
- chr7:8,262,264–8,344,516, 2 genes, copy number 5 (within-gene range 4–5): AC007128.1, AC007128.2.
- chr8:16,107,878–16,567,490, 3 genes, copy number 5: MSR1, CCT3P1, MRPL49P2.
- chr8:22,367,278–22,434,497, 3 genes, copy number 30: SLC39A14, AC105910.1, RNU6-336P.
- chr9:38,360,427–38,424,454, 3 genes, copy number 35: AL135785.1, ALDH1B1, IGFBPL1.
- chr12:55,716,036–55,830,824, 13 genes, copy number 5 (within-gene range 2–5): AC009779.3, BLOC1S1, RDH5, CD63, AC009779.2, Metazoa_SRP, AC009779.1, GDF11, SARNP, AC023055.1, AC073487.1, ORMDL2, DNAJC14.
- chr12:56,521,820–56,596,193, 2 genes, copy number 33 (within-gene range 4–33): RBMS2, RNU6-343P.
- chr12:62,260,338–62,417,431, 4 genes, copy number 37 (within-gene range 2–37): USP15, MIR6125, RNU6-595P, Metazoa_SRP.
- chr12:68,746,125–68,971,570, 7 genes, copy number 29 (within-gene range 2–30): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM.
- chr12:68,957,377–68,957,677, 1 gene, copy number 29 (within-gene range 29–30): PRELID2P1.

Autosomal genes at a single copy (total copy number 1): 1,896. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
